Somatic mutation profile of tumor specimen TCGA-CV-A6JD-01A (aliquot TCGA-CV-A6JD-01A-11D-A31L-08) from TCGA case TCGA-CV-A6JD, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; Tumor grade: G3; Age at diagnosis: 82.1 years (29,988 days).
Specimen TCGA-CV-A6JD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 864a2882-1a84-4643-8c32-efc8689296e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A6JD-10A (Blood Derived Normal), aliquot TCGA-CV-A6JD-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32cd2e06-e67c-4a63-948e-651c4387daa4

The open-access MAF lists 103 somatic variants for this specimen: 79 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 23, Nonsense Mutation 7, Frame Shift Del 3, Frame Shift Ins 2, Intron 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 22/44 reads (50%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, varscan2
- HRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 29/71 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs104894228, CM060018, COSV54236651, COSV54236730, COSV54241641; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.422G>T p.C141F | Missense Mutation (SNP) | VAF 25/66 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781288, CM993216, COSV52664953, COSV52926626, COSV53155598; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 26/121 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs786201057, CM102351, CM157948, COSV52667346, COSV52673504, COSV52688693, COSV99037266; ClinVar: likely pathogenic / pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ABCG4 | c.1573G>A p.G525R | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs764136296, COSV100266914; called by muse, mutect2, varscan2
- ABLIM3 | c.193A>G p.N65D | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.245); catalogued as COSV100448621; called by muse, mutect2, varscan2
- AKAP4 | c.2197A>G p.K733E | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.95); PolyPhen benign (0.018); catalogued as COSV100654321; called by muse, mutect2, varscan2
- ARGFX | c.860T>C p.M287T | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100544171; called by muse, mutect2, varscan2
- ATF4 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV100307776; called by muse, mutect2, varscan2
- ATN1 | c.2611A>G p.T871A | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.151); catalogued as rs781891087, COSV100755890; called by muse, mutect2, varscan2
- ATP13A3 | c.2902T>C p.F968L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.408); catalogued as COSV99757418; called by muse, mutect2, varscan2
- BCR | c.2172G>T p.K724N | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV100006803; called by muse, mutect2
- BRWD1 | c.6808C>T p.R2270* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as rs758176006, COSV100313770; called by muse, mutect2, varscan2
- C16orf89 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.815); catalogued as COSV100280900; called by muse, mutect2, varscan2
- C2orf73 | c.293C>A p.S98Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV100471392; called by muse, mutect2, varscan2
- CAPN5 | c.128G>A p.G43D | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.028); catalogued as rs781940282, COSV99582404; called by muse, mutect2, varscan2
- CASP8 | c.1406C>T p.T469I (on ENST00000432109 / NM_033355.3; = p.T486I on NM_001228.4) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99630560; called by muse, mutect2, varscan2
- CCDC158 | c.2401C>T p.R801C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs749566655, COSV66355210; called by muse, mutect2, varscan2
- CCDC180 | c.465G>A p.M155I | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV100827119, COSV63833373; called by muse, mutect2, varscan2
- CCDC74A | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV99723819; called by muse, mutect2, varscan2
- CCNL1 | c.584G>A p.C195Y | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99904273; called by muse, mutect2, varscan2
- CGB2 | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs1395325750, COSV100031716; called by mutect2, varscan2
- COL3A1 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58582021, COSV58584742; called by muse, varscan2
- CRACD | c.3337G>T p.A1113S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99949703; called by muse, mutect2, varscan2
- CSTF2 | c.1147C>A p.L383I | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV100880821; called by muse, mutect2, varscan2
- DENND2B | c.1127C>A p.S376* | Nonsense Mutation (SNP) | VAF 60/227 reads (26%) | catalogued as COSV100567672; called by muse, mutect2, varscan2
- DHRS11 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs144559068; called by muse, mutect2, varscan2
- DZIP3 | c.2560G>A p.A854T | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.46); catalogued as rs773671554, COSV100847943; called by muse, mutect2, varscan2
- EP300 | c.4751T>C p.L1584P | Missense Mutation (SNP) | VAF 76/255 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54329918, COSV99609371; called by muse, mutect2, varscan2
- FAM217B | c.758A>G p.H253R | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100674603; called by muse, mutect2, varscan2
- FAT1 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 105/189 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71674265; called by muse, mutect2, varscan2
- FATE1 | c.235-1G>A p.X79_splice | Splice Site (SNP) | VAF 17/63 reads (27%) | catalogued as COSV100948181, COSV64849169; called by muse, mutect2, varscan2
- HCN1 | c.1315T>C p.Y439H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV57498716; called by muse, mutect2, varscan2
- HLA-B | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as rs776780353, COSV69520663, COSV69521156; called by muse, mutect2, varscan2
- HS3ST3A1 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); catalogued as rs777054228, COSV52380387; called by muse, mutect2, varscan2
- HTR2C | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 140/466 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV52201275, COSV52220450; called by muse, mutect2, varscan2
- JADE3 | c.668G>T p.C223F | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99510103; called by muse, mutect2, varscan2
- KCNQ5 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1358941689, COSV100572609; called by muse, mutect2, varscan2
- KMT2A | c.6745C>T p.P2249S | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV100629381; called by muse, mutect2, varscan2
- MAGI2 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs758636095, COSV62632078, COSV62644595; called by muse, mutect2, varscan2
- MINK1 | c.3562C>A p.H1188N | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99545174; called by muse, mutect2, varscan2
- MTMR6 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs759255438, COSV101110815; called by muse, mutect2, varscan2
- MYBBP1A | c.3049G>A p.V1017I | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as rs765383465, COSV99626590; called by muse, mutect2, varscan2
- MYOD1 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV100000352; called by muse, mutect2, varscan2
- NONO | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.296); catalogued as rs779961109, COSV52137204; called by muse, mutect2, varscan2
- NRBP2 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.149); catalogued as rs370686102, COSV100589165; called by muse, mutect2, varscan2
- NTRK2 | c.776A>G p.D259G | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT tolerated (0.33); PolyPhen probably damaging (1); catalogued as COSV99457390; called by muse, mutect2, varscan2
- NUMA1 | c.4087G>A p.A1363T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.053); catalogued as rs766815206, COSV100706425; called by muse, mutect2, varscan2
- OR6K3 | c.71C>T p.T24I (on ENST00000368146; = p.T8I on NM_001005327.2) | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100933872; called by muse, mutect2, varscan2
- OR6X1 | c.914G>T p.C305F | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100020612; called by muse, mutect2, varscan2
- P2RX3 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776353099, COSV99628824; called by muse, mutect2, varscan2
- PARD3B | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370874606; called by muse, mutect2, varscan2
- PCDH9 | c.3308C>A p.T1103N (on ENST00000377865 / NM_203487.3; = p.T1069N on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1466754652, COSV100122344; called by muse, mutect2, varscan2
- PHYHD1 | c.315C>T p.H105= | Splice Region (SNP) | VAF 22/95 reads (23%) | catalogued as rs774654680, COSV100455210; called by muse, mutect2, varscan2
- PREX1 | c.3530G>A p.R1177Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1359762426, COSV100906622; called by muse, mutect2, varscan2
- PRR19 | c.352C>G p.P118A | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0.022); catalogued as COSV100004015, COSV56624041, COSV56625287; called by muse, mutect2, varscan2
- PSMD2 | c.500C>A p.A167D | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV100031914; called by muse, mutect2, varscan2
- PTPRT | c.3468C>A p.F1156L | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100629129, COSV62023576; called by muse, mutect2, varscan2
- PTPRU | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 162/264 reads (61%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs746575215, COSV100112689, COSV60530180; called by muse, mutect2, varscan2
- RAC1 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV61821605; called by muse, mutect2, varscan2
- RAD51AP1 | c.515C>T p.A172V (on ENST00000228843 / NM_001130862.2; = p.A155V on NM_006479.5) | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as rs1468723998, COSV99961441; called by muse, mutect2, varscan2
- RBMXL2 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.924); catalogued as rs747323071, COSV100182380; called by muse, mutect2, varscan2
- SEC31A | c.1336C>T p.Q446* | Nonsense Mutation (SNP) | VAF 19/79 reads (24%) | catalogued as COSV100022155; called by muse, mutect2, varscan2
- SHROOM3 | c.874C>T p.R292* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as rs202185868, COSV99933865, COSV99934912; called by muse, mutect2, varscan2
- STAT2 | c.1467dup p.K490Qfs*41 | Frame Shift Ins (INS) | VAF 21/92 reads (23%) | catalogued as rs763294380; called by mutect2, varscan2
- STRIP2 | c.1038G>T p.R346S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99973369, COSV99974026; called by muse, mutect2, varscan2
- STX1B | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99288264; called by muse, mutect2, varscan2
- SYT16 | c.1562G>A p.R521Q | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); catalogued as rs745444147, COSV70857613; called by muse, mutect2, varscan2
- TIMM23 | c.605G>A p.G202D | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs150556806; called by muse, mutect2, varscan2
- TNIP1 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.02); catalogued as rs1343578412, COSV100161625; called by muse, mutect2, varscan2
- TTN | c.33785A>T p.K11262M (on ENST00000591111; = p.K10335M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/267 reads (28%) | PolyPhen possibly damaging (0.478); catalogued as COSV100622498; called by muse, mutect2, varscan2
- UGT2B28 | c.1484G>T p.G495V | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs763922496, COSV100158943; called by muse, mutect2, varscan2
- VAV2 | c.2455G>A p.G819S (on ENST00000371850 / NM_001134398.2; = p.G780S on NM_003371.4) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.138); catalogued as rs148033881; called by muse, mutect2, varscan2
- WDFY3 | c.7583G>A p.R2528H | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1334967892, COSV99884739; called by muse, mutect2, varscan2
- ZNF410 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); catalogued as COSV100206534; called by muse, mutect2, varscan2
- KDM5C | c.1128dup p.K377* | Frame Shift Ins (INS) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- NFATC2 | c.1126_1127delinsA p.P376Tfs*15 | Frame Shift Del (DEL) | VAF 56/248 reads (23%) | called by pindel, varscan2*
- PTPN14 | c.2175del p.M726Cfs*34 | Frame Shift Del (DEL) | VAF 17/69 reads (25%) | called by mutect2, pindel, varscan2
- PTPRG | c.3265del p.L1089Wfs*4 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, varscan2
- ARHGEF17 | c.3444C>T p.L1148= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as rs200939752, COSV99735419; called by muse, mutect2, varscan2
- ARHGEF19 | c.1533C>T p.F511= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as COSV99580638; called by muse, mutect2, varscan2
- BCAN | c.1452C>T p.S484= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs746563491, COSV100228312; called by muse, mutect2, varscan2
- C5AR2 | c.411C>T p.L137= | Silent (SNP) | VAF 41/166 reads (25%) | catalogued as rs754371545, COSV99953844; called by muse, mutect2, varscan2
- CSMD3 | c.7075T>C p.L2359= (on ENST00000297405 / NM_001363185.1; = p.L2255= on NM_052900.3) | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs1486774313, COSV52149783, COSV99841737; called by muse, mutect2, varscan2
- DUSP2 | c.6G>T p.G2= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs557719539, COSV99997155; called by muse, varscan2
- HTR1E | c.660G>A p.R220= | Silent (SNP) | VAF 40/142 reads (28%) | catalogued as rs753692471, COSV100541201; called by muse, mutect2, varscan2
- IQCN | c.2826G>A p.A942= | Silent (SNP) | VAF 33/124 reads (27%) | catalogued as rs535880358, COSV100828375; called by muse, mutect2, varscan2
- MC1R | c.717C>T p.G239= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as rs34490506; ClinVar: likely benign; called by muse, mutect2, varscan2
- NES | c.3702G>A p.G1234= | Silent (SNP) | VAF 56/185 reads (30%) | catalogued as COSV100957942; called by muse, mutect2, varscan2
- NID2 | c.3687G>A p.V1229= | Silent (SNP) | VAF 38/128 reads (30%) | catalogued as COSV99356982; called by muse, mutect2, varscan2
- NUP107 | c.1323C>T p.V441= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV99971929; called by muse, mutect2, varscan2
- OR11A1 | c.798C>A p.V266= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV101010724; called by muse, mutect2, varscan2
- OR5D14 | c.894C>T p.D298= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs141238594; called by muse, mutect2, varscan2
- PTPRG | c.3265C>T p.L1089= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99876188; called by mutect2, varscan2
- RECQL4 | c.2424C>T p.D808= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs377301609; ClinVar: likely benign; called by muse, mutect2, varscan2
- RNF207 | c.159G>A p.A53= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV100933752; called by muse, mutect2, varscan2
- SLC8B1 | c.147C>T p.P49= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs267603316, COSV99176789; called by muse, mutect2, varscan2
- SMG5 | c.1821C>T p.C607= | Silent (SNP) | VAF 54/191 reads (28%) | catalogued as rs185984683, COSV62434581; called by muse, mutect2, varscan2
- THNSL2 | c.402C>T p.H134= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as rs149479181; called by muse, mutect2, varscan2
- TRO | c.1920C>T p.R640= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as rs756724040, COSV51504060; called by muse, mutect2, varscan2
- XRCC3 | c.150G>A p.L50= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs763661308, COSV100721312; called by muse, mutect2, varscan2
- ZNF781 | c.246T>C p.T82= | Silent (SNP) | VAF 31/107 reads (29%) | catalogued as COSV100669318; called by muse, mutect2, varscan2
- CYP11B1 | c.239+134_239+137dup | Intron (INS) | VAF 24/59 reads (41%) | called by mutect2, pindel, varscan2
